Somatic mutation profile of tumor specimen TCGA-B9-A5W7-01A (aliquot TCGA-B9-A5W7-01A-11D-A31X-10) from TCGA case TCGA-B9-A5W7, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 47.8 years (17,465 days).
Specimen TCGA-B9-A5W7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1bcf856-3d0e-47f1-b5f4-6b9177bb3bcd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-A5W7-10A (Blood Derived Normal), aliquot TCGA-B9-A5W7-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/482644d6-9a54-46e3-892d-a51e6db8f29f

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, In Frame Del 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA2D1 | c.3155A>C p.Y1052S (on ENST00000356253 / NM_001366867.1; = p.Y1040S on NM_000722.4) | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV62383402; called by muse, mutect2, varscan2
- GRIK5 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs763923047, COSV53480930; called by muse, mutect2, varscan2
- MUC4 | c.14494C>T p.R4832C (on ENST00000463781 / NM_018406.7; = p.R596C on NM_004532.6) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV57788375; called by muse, mutect2
- P2RY2 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60776722; called by muse, mutect2, varscan2
- PIK3R4 | c.2682_2684del p.S895del | In Frame Del (DEL) | VAF 12/114 reads (11%) | catalogued as rs1368423361; called by mutect2, pindel
- TGM1 | c.2307C>A p.S769R | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM162739; called by muse, mutect2
- TM7SF2 | c.1208A>G p.Q403R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54205111; called by mutect2, varscan2
- COPS4 | c.1118del p.Q373Rfs*9 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | called by mutect2, pindel, varscan2
- TSPAN33 | c.399C>A p.A133= | Silent (SNP) | VAF 46/72 reads (64%) | catalogued as COSV56826845; called by muse, mutect2, varscan2
